TCGA case TCGA-AG-3883 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b6e6e715-ccc5-474f-860a-a10bf1962936

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 69.6 years (25,415 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 31 days.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 15; Lymphatic invasion present: Yes; Vascular invasion present: Yes.

Follow-up (1 entry)
- Days to follow up: 31 days; Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 2.39 ng/mL.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AG-3883-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-AG-3883-01A-01-BS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 30.
  Slide TCGA-AG-3883-01A-02-BS2: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 40.
- Sample TCGA-AG-3883-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-AG-3883-10A, TCGA-AG-3883-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 2.39; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 31 days; disease-specific survival: no event (censored), 31 days; progression-free interval: no event (censored), 31 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AG-3883-01A-02D-0903-01): tumor purity 0.56, ploidy 2.99, whole-genome doublings 1.
